Somatic mutation profile of tumor specimen 0DVPOW from CCDI case PBCMZF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,548 days).
Specimen 0DVPOW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0b436c6-f498-4fb1-af2f-9f802b01c06d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPPA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeedd8d8-e693-4f3a-90d1-eb07f7685afb

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOT1L | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs781157426; called by muse, mutect2, varscan2
- ITGA6 | c.2441+1G>A p.X814_splice (on ENST00000442250; = p.X775_splice on NM_000210.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 172/539 reads (32%) | catalogued as rs1559149872, COSV51229497; called by muse, mutect2, varscan2
- PPP1R3A | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 35/920 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99493992; called by muse, mutect2
- PRKD1 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 86/346 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59558168; called by muse, mutect2
- SLC26A7 | c.821A>T p.Y274F | Missense Mutation (SNP) | VAF 23/469 reads (5%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.596); catalogued as COSV99404294; called by muse, mutect2
- TOB2 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 113/413 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPSF1 | c.2535C>T p.L845= | Silent (SNP) | VAF 156/404 reads (39%) | catalogued as rs376816034; called by muse, mutect2, varscan2
